Somatic mutation profile of tumor specimen MP2PRT-PAVDBJ-TMP1-A (aliquot MP2PRT-PAVDBJ-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVDBJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,469 days).
Specimen MP2PRT-PAVDBJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c35f1b83-63f2-44fc-8209-fd833da9b0bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDBJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDBJ-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7919e7f5-811c-4f7f-98fc-ac6780bd7795

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 13, Silent 6, Nonsense Mutation 2, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 127/336 reads (38%) | catalogued as rs72559730, CM994413; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 92/308 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGB | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1054105863; called by muse, mutect2, varscan2
- AHNAK | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 161/377 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs754563030; called by muse, mutect2, varscan2
- ASPHD1 | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 150/365 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as rs749695199; called by muse, mutect2, varscan2
- CCDC78 | c.765+1G>C p.X255_splice | Splice Site (SNP) | VAF 79/195 reads (41%) | catalogued as rs1171426081; called by muse, mutect2, varscan2
- CSNK1G3 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 60/181 reads (33%) | catalogued as rs935733993, COSV62053871; called by muse, mutect2, varscan2
- LRRC49 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs778263578, COSV51436142; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 93/478 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RASGRF2 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 93/321 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs751655078, COSV54132674; called by muse, mutect2, varscan2
- RYR2 | c.3092G>A p.R1031H | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.899); catalogued as rs772646981, COSV100769764; called by muse, mutect2, varscan2
- TTN | c.94745G>A p.R31582H (on ENST00000591111; = p.R24158H on NM_003319.4) | Missense Mutation (SNP) | VAF 128/292 reads (44%) | PolyPhen probably damaging (1); catalogued as rs369081242; ClinVar: conflicting interpretations of pathogenicity; called by muse, varscan2
- CACNA1F | c.2429_2430insAGA p.E825dup | In Frame Ins (INS) | VAF 61/347 reads (18%) | called by mutect2, pindel, varscan2
- GATA1 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 195/791 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- OR5D14 | c.422G>T p.R141M | Missense Mutation (SNP) | VAF 103/324 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- RTL1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 120/535 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TTBK1 | c.1955G>C p.R652T | Missense Mutation (SNP) | VAF 17/695 reads (2%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- CADPS2 | c.432C>T p.N144= | Silent (SNP) | VAF 77/207 reads (37%) | catalogued as rs779114368; called by muse, mutect2, varscan2
- CTF1 | c.102G>A p.A34= | Silent (SNP) | VAF 115/260 reads (44%) | catalogued as rs727504837, COSV99288505; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH11 | c.4371T>A p.T1457= | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as rs1386066747; called by muse, mutect2
- GGN | c.1380G>A p.P460= | Silent (SNP) | VAF 22/677 reads (3%) | catalogued as rs998967452; called by muse, mutect2
- MYO15A | c.6786C>T p.R2262= | Silent (SNP) | VAF 38/556 reads (7%) | catalogued as rs372462304; called by muse, mutect2
- STK31 | c.33C>T p.S11= | Silent (SNP) | VAF 82/276 reads (30%) | catalogued as rs776358668, COSV63455581, COSV63455969; called by muse, mutect2, varscan2
